Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7887, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7887-01A (Primary Tumor).

[page 1 of 4]
HISTOPATHOLOGY REPORT

ORIGINAL REPORT

SPECIMEN:

- A: Gallbladder
- B: Retroperitoneal lymph node
- C: Pancreatic duct margin
- D: Pancreatic cyst wall
- E: Whipple's resection
- F: Pancreatic neck

CLINICAL HISTORY:

Mass at head of pancreas.
Infectious patient: No
Immunocompromised: No
History of Neoplasm: No

DIAGNOSIS:

- A. GALLBLADDER, CHOLECYSTECTOMY:
- NEGATIVE FOR MALIGNANCY.
- B. LYMPH NODE, RETROPERITONEAL, BIOPSY:
- TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
- C. PANCREATIC DUCT MARGIN BIOPSY:
- INVOLVED BY INVASIVE ADENOCARCINOMA.
- D. PANCREATIC CYST WALL BIOPSY:
- FOCUS OF INVASIVE ADENOCARCINOMA.
- E. SMALL BOWEL AND HEAD OF PANCREAS, WHIPPLE'S RESECTION:
- PANCREATIC DUCTAL ADENOCARCINOMA, MODERATELY DIFFERENTIATED (PT3N1BMX).
- LYMPHOVASCULAR INVASION IS IDENTIFIED.
- PERINEURAL INVASION IS IDENTIFIED.
- THREE LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (3/3).
- PANCREATIC NECK AND UNCTATE MARGINS ARE INVOLVED BY TUMOR.
- SEE SURGICAL SYNOPTIC REPORT FOR DETAILS.
- F. PANCREATIC NECK BIOPSY:
- THE NECK MARGIN IS INVOLVED BY INVASIVE ADENOCARCINOMA.
- FIBROSIS WITH ACUTE INFLAMMATION.

[page 2 of 4]
HISTOPATHOLOGY REPORT

DIAGNOSIS:

GROSS DESCRIPTION:

A: The specimen consists of a gallbladder measuring 7.7 x 2.5 x 1.5 cm. Opening of the gallbladder reveals no stones. The mucosa is unremarkable. The wall thickness is 0.2 cm. Cut sections are unremarkable. Two representative sections and the cystic duct margin are submitted in one cassette.

B: The specimen consists of two pieces of tan colored tissue measuring 2.0 x 1.0 x 0.7 cm and 1.7 x 0.7 x 0.4 cm. The specimen is submitted in toto as follows:

- B1 - larger piece bisected.
- B2 - smaller piece bisected.

C: Ring of tissue 1.0 x 0.6 x 0.2 cm as measured. Submitted in toto for QS.

D: Irregular fragment of tan/grey tissue, 1.3 x 0.6 x 0.2 cm. One surface is grey and smooth. Bisected and submitted in toto for QS.

E: The specimen consists of a portion of small bowel with head of pancreas and neck of pancreas. The specimen is painted with silver nitrate and the pancreatic neck is painted blue. The uncinate margin is painted orange dye. Cut sections reveal a tumor mass involving the head of pancreas that measures 5.5 x 3.5 x 4.5 cm. A cystic component measuring 3.0 cm in diameter that contains blood is noted. No other mass lesions are identified grossly. Representative sections are submitted as follows:

- E1 and E2 - proximal bowel resection margin en face.
- E3 and E4 - distal bowel resection margin en face.

[page 3 of 4]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

E5 through E7 - pancreatic neck margin en face.
E8 through E11 - uncinate margin en face.
E12 through E22 - tumor.
E23 through E25 - random sections from bowel.

F: The specimen consists of one piece of tan colored tissue measuring 3.2 x 1.8 x 0.3 cm. The specimen is sectioned and submitted in toto in three cassettes.

FROZEN SECTION MICROSCOPIC:

C: Dense fibrous tissue with clustered atypical glandular elements. Malignancy cannot be excluded. The epithelium of the mass pancreatic duct shows mild reactive changes only.

D: Fibrosis, purulent inflammation and atypical ductal epithelium. Neoplastic change in duct epithelium not included. Inflammatory cystic change associated with a neoplastic mass favored.

FROZEN SECTION DIAGNOSIS:

- C: PANCREATIC DUCT MARGIN:
- ATYPICAL DUCTAL ELEMENTS.
- MALIGNANCY NOT EXCLUDED.
- DEFER TO FIXED SECTION FOR FINAL EVALUATION.
- D: PANCREATIC CYST WALL:
- INFLAMMATORY CYST CHANGE WITH ATYPICAL DUCT EPITHELIUM,
- NEOPLASIA/PANIN NOT EXCLUDED.
- DEFER TO PERMANENTS FOR FINAL EVALUATION.

MICROSCOPIC DESCRIPTION:

A-P. Surgical synoptic report.

Microscopic:

Specimen type:	Pancreaticoduodenectomy (Whipple's resection, partial pancreatectomy)
Tumor site:	Pancreatic head
Tumor size:	5.5 x 4.8 x 3.5 cm
Other organs resected:	Gallbladder

[page 4 of 4]
HISTOPATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Histologic type: Ductal adenocarcinoma, not otherwise specified.
Histologic grade: Moderately differentiated (G2)
Pathologic staging (pTNM):
Primary tumor (pT): pT3 (invasion of duodenal wall)
Region lymph nodes (pN): pN1b
Number examined - 10 lymph nodes
Number involved - 3 lymph nodes
Distant metastasis (pM): pMx
Margins: Pancreatic and uncinate margins are involved by
invasive adenocarcinoma.
Lymphovascular invasion: Present, focal
Perineural invasion: Present
Additional pathologic findings: Pancreatic intraepithelial neoplasia (PanIN-3)
Acute and chronic pancreatitis.

Source: NCI Genomic Data Commons file 1eaff947-8c21-4426-80d9-7e2de2c1bc8a (TCGA-IB-7887.596670EA-DFC3-4E9B-AB35-8DD63522F40F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).